Somatic mutation profile of tumor specimen MMRF_1202_2_BM_CD138pos (aliquot MMRF_1202_2_BM_CD138pos_T1_KBS5U_L05837) from MMRF case MMRF_1202, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.8 years (21,838 days).
Specimen MMRF_1202_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93945669-9157-4e82-bac6-1d0b45645890.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1202_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1202_1_PB_Whole_C2_KAS5U_L01382; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/afa16dd9-b84e-4252-95fb-94394e4c2e75

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGDCC3 | c.1658G>A p.G553D | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60080064; called by muse, mutect2
- CEP85L | c.*3717C>T | 3'UTR (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- UGGT1 | c.*1332G>A | 3'UTR (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
